TCGA case TCGA-D3-A51T — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Lymph nodes; Tissue source site: MD Anderson. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/791d3824-890f-43f2-b545-c7266506d716

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 59 years; Vital status: Alive.

Diagnoses (4)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C77.3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph nodes of axilla or arm; Classification of tumor: Progression; Age at diagnosis: 59.8 years (21,857 days); Days to diagnosis: 34 days; Prior treatment: No; Days to last follow up: 818 days (2.2 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: IV; Sites of involvement: Skin, Trunk; Ulceration indicator: Yes.
   Pathology details: Breslow thickness category: >4.0 mm.
   Recorded as not given: Radiation Therapy, NOS.
3. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 59.7 years (21,823 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T4b; AJCC pathologic N: N1b; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 108 days; Days to treatment end: 122 days; Treatment dose: 30 Gy; Treatment outcome: Complete Response; Number of fractions: 5; Treatment anatomic sites: Regional Site.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.
4. Melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin of trunk; Classification of tumor: Subsequent Primary; Age at diagnosis: 60.3 years (22,033 days); Days to diagnosis: 210 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 337 days.
   Recorded as not given: Pharmaceutical Therapy, NOS, for initial diagnosis; Radiation Therapy, NOS, for initial diagnosis.

Follow-up (2 entries)
- Days to follow up: 458 days (1.3 years); Disease response: Tumor Free.
- Days to follow up: 818 days (2.2 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 16.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 92 kg; Height: 152 cm; BMI: 39.8.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-D3-A51T-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 100 mg.
  Slide TCGA-D3-A51T-06A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 97; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-D3-A51T-06Z: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-D3-A51T-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Breslow thickness at diagnosis: 4.2; Radiation therapy to primary: No; Primary location: Regional Lymph Node; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No.
- Sites of primary melanomas, Site: Submitted tumor site: Trunk; Melanoma primary count: 1.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Subsequent known primaries: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 818 days; disease-specific survival: no event (censored), 818 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 210 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-D3-A51T-06A-11D-A25P-01): tumor purity 0.83, ploidy 1.87, whole-genome doublings 0.
